Somatic mutation profile of tumor specimen 0DPX42 from CCDI case PBCEID, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,806 days).
Specimen 0DPX42: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 390b8127-e22a-42cb-b700-99a078b413d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX3D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26eb3d3c-82e5-45e3-a4ac-42e9c34467dc

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, 3'UTR 4, Frame Shift Del 4, Intron 3, Nonsense Mutation 3, 3'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 82/236 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- CADPS | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs752666502, COSV51885333; called by muse, mutect2
- COL5A1 | c.4964G>A p.W1655* | Nonsense Mutation (SNP) | VAF 56/624 reads (9%) | catalogued as COSV100880247; called by muse, mutect2
- DEFB114 | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 115/263 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs1330637884; called by muse, mutect2, varscan2
- DMRTC2 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54188218; called by muse, mutect2, varscan2
- GRAP2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs755717282; called by muse, mutect2, varscan2
- MYH2 | c.1993A>T p.M665L | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs1230352118; called by muse, mutect2
- NUTM2F | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 204/677 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs549762125; called by muse, mutect2, varscan2
- PDGFRA | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 239/357 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57268608; called by muse, mutect2, varscan2
- PRR3 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 150/281 reads (53%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as rs1490995917, COSV64835353; called by muse, mutect2, varscan2
- PTPRH | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 98/106 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771367694, COSV99670905; called by muse, mutect2
- STARD4 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 202/465 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419199229; called by muse, mutect2, varscan2
- TBX22 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 136/271 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs774880507; called by muse, mutect2, varscan2
- TET3 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 146/264 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs1401175582, COSV59880412; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 184/298 reads (62%) | catalogued as rs587780067; called by pindel, varscan2
- TPPP | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 134/345 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs767604979; called by muse, mutect2, varscan2
- UNC5D | c.1117+1G>T p.X373_splice | Splice Site (SNP) | VAF 67/266 reads (25%) | catalogued as COSV54818588; called by muse, mutect2, varscan2
- ATRX | c.6338_6341del p.F2113Sfs*9 | Frame Shift Del (DEL) | VAF 104/269 reads (39%) | called by pindel, varscan2
- BCHE | c.147del p.F49Lfs*5 | Frame Shift Del (DEL) | VAF 45/273 reads (16%) | called by mutect2, pindel, varscan2
- BMP2K | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BNC1 | c.2567T>C p.L856P | Missense Mutation (SNP) | VAF 124/236 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLMN | c.2505C>G p.S835R | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- DDX19A | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 138/365 reads (38%) | called by muse, mutect2, varscan2
- FBXL18 | c.1864G>C p.V622L | Missense Mutation (SNP) | VAF 184/392 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.179); called by muse, mutect2
- MDC1 | c.6019G>A p.V2007I | Missense Mutation (SNP) | VAF 154/299 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NPC1 | c.3477G>A p.M1159I | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PNISR | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 25/599 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- PP2D1 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); called by mutect2, varscan2
- PROCA1 | c.714_716del p.K240del (on ENST00000439862 / NM_001366301.1; = p.K212del on NM_152465.3 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 138/322 reads (43%) | called by pindel, varscan2
- RTTN | c.3241C>T p.Q1081* | Nonsense Mutation (SNP) | VAF 174/362 reads (48%) | called by muse, mutect2, varscan2
- SLC25A46 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 130/254 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPATA31A1 | c.2519del p.A840Vfs*30 | Frame Shift Del (DEL) | VAF 71/660 reads (11%) | called by mutect2, pindel, varscan2
- TBC1D30 | c.2116G>T p.G706C (on ENST00000542120; = p.G543C on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/360 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- THADA | c.4499T>C p.I1500T | Missense Mutation (SNP) | VAF 150/327 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UGT3A1 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- WSB1 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 131/272 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XCL1 | c.226T>A p.W76R | Missense Mutation (SNP) | VAF 210/437 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM3 | c.2965T>G p.L989V | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ANO8 | c.1701G>A p.A567= | Silent (SNP) | VAF 86/182 reads (47%) | catalogued as rs754025744; called by muse, mutect2, varscan2
- CEP70 | c.1302T>C p.G434= | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as COSV53874737; called by muse, mutect2, varscan2
- GPR149 | c.1245A>G p.E415= | Silent (SNP) | VAF 177/227 reads (78%) | called by muse, mutect2, varscan2
- MS4A7 | c.99C>T p.N33= | Silent (SNP) | VAF 173/363 reads (48%) | catalogued as rs763227318, COSV55730961; called by muse, mutect2, varscan2
- N6AMT1 | c.123C>G p.A41= | Silent (SNP) | VAF 84/232 reads (36%) | catalogued as COSV58134860; called by muse, mutect2, varscan2
- RGS9 | c.1629C>T p.S543= | Silent (SNP) | VAF 146/278 reads (53%) | catalogued as rs369706360; called by muse, mutect2, varscan2
- SCYL2 | c.2685T>C p.G895= | Silent (SNP) | VAF 168/357 reads (47%) | called by muse, mutect2, varscan2
- STAT5A | c.1872C>T p.I624= | Silent (SNP) | VAF 137/307 reads (45%) | catalogued as rs143308879; called by muse, mutect2, varscan2
- CASZ1 | c.*2G>T | 3'UTR (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- MRPL50 | c.*50G>A | 3'UTR (SNP) | VAF 54/134 reads (40%) | catalogued as rs754809552; called by muse, varscan2
- OR2L5 | c.*14G>A | 3'UTR (SNP) | VAF 117/240 reads (49%) | called by muse, mutect2, varscan2
- OR2T27 | chr1:248649907 T>C | 3'Flank (SNP) | VAF 44/225 reads (20%) | called by muse, mutect2
- RBL2 | c.3084+91G>A | Intron (SNP) | VAF 37/82 reads (45%) | catalogued as rs955725513; called by muse, varscan2
- RBM44 | c.-98-2489A>T | Intron (SNP) | VAF 18/429 reads (4%) | called by muse, mutect2
- SATB2 | c.598-16_598-15del | Intron (DEL) | VAF 82/232 reads (35%) | called by pindel, varscan2
- SYT1 | c.*58A>G | 3'UTR (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
